Surgical pathology report (de-identified scan), TCGA case TCGA-GC-A3RC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-GC-A3RC-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Final Report

Temporary Copy

Case:

Collection:

Created by:

Final Diagnosis

Left ureter with FS:

Ureter with chronic inflammation; negative for dysplasia.

Right ureter with FS:

Ureter with chronic inflammation; negative evidence of dysplasia.

Appendix:

Anatomically normal appendix.

ICD-O-3

Carcinoma, urothelial, NOS

812013

Site: bladder, wall, NOS

C67.9

3-30-12 RD

Bladder, total cystectomy:

- Invasive urothelial carcinoma.
- Tumor has high-grade histology.
- Maximum tumor size: 5.7 cm in greatest dimension.
- Associated epithelial lesion (none identified).
- Microscopic tumor extension to the ureteral orifice (bilateral).
- Prostatic exam reveals no evidence of prostatic invasion.
- Seminal vesicles are unremarkable with no evidence of invasion.
- Lymphovascular invasion is identified.
- Margins:
- Tumor invades to 0.3 cm of the anterior margin.
- All inked margins of resection appear free of tumor.
- Right pelvic lymph nodes:
- Two (2) lymph nodes negative for metastatic tumor.
- Left pelvic lymph nodes:
- Seven (7) lymph nodes negative for metastatic tumor.

AJCC pathologic stage: pT2b,N0,MX.

Clinical Information

Bladder mass.

Frozen Section Diagnosis

FSA Left ureter - lumen with urothelium negative for dysplasia.

ICD-9 Discrepancy		X

[page 2 of 4]
Surgical Pathology Final Report

Temporary Copy

Case:

Collected:

Order ref by:

FSB Right ureter: Lumen with urothelium negative for dysplasia.
(Focal ch. inf. with giant cells in periureteral fat).

Gross Description

"A, FSA, Left ureter." Received is frozen section control tissue. "FSA," all.

"B, NFSB." Received after frozen section is a 0.7 x 0.5 x 0.2 cm yellow-tan to gray-tan tissue fragment. A portion of the specimen has been submitted for frozen section in cassette "FSB." "B," all.

"C, Appendix." Received is a 4.2 x 0.5 cm appendix with attached periappendiceal fat. The proximal margin will be inked black, shaved and submitted. No masses or lesions are grossly identified on the serosa. No masses or lesions are grossly identified in the appendix. "C," representative.

"D, Bladder." Received is a bladder with attached prostate gland and bilateral vasa deferentia and seminal vesicles, which has an overall measurement of 12.6 x 7.2 x 4.7 cm. The prostate gland and bladder have been previously opened on their anterior aspect. The prostatic apex will be inked yellow, shaved and submitted. The remainder of the prostate gland will be inked orange. There is a 5.7 x 4.4 cm firm, friable mass on the mucosa of the anterior aspect of the bladder. The mass grossly appears to come to within 4.7 cm of the prostatic apex. The mass invades the wall of the bladder and grossly appears to come to within 0.3 cm of the overlying perivesicular tissue, which has been previously inked black. The mass involves the mucosa in the region of both the left and right ureteral orifices but does not grossly appear to involve the lumen of either orifice. The remaining bladder mucosa is edematous. No masses or lesions are grossly identified in the prostate gland.

Free in the container is a smaller container labeled "fixed specimen", which has a 2.1 x 1.5 cm yellow-tan soft tissue fragment and a 3.5 x 0.3 cm linear tissue fragment. The linear tissue fragment will be bisected and of these tissue fragments will be submitted in toto. "D1," apex; "D2-D4," mass; "D5," left ureteral orifice with mass; "D6," right ureteral orifice with mass; "D7," trigone; "D8," posterior bladder wall; "D9," dome of bladder; "D10," left vas deferens and seminal vesicle; "D11," right vas deferens and seminal vesicle; "D12-D19," prostate gland sublabeled "D12-D13," left posterior quadrant; "D14-D15," right posterior quadrant; "D16-D17," left anterior quadrant; "D18-D19," right anterior quadrant; "D10," tissue in smaller container labeled "fixed specimen". See attached drawing.

"E, Right pelvic lymph nodes." Received is a 6.2 x 3.8 x 2.1 cm aggregate of yellow-tan, lobulated tissue. On sectioning, there are 11 possible lymph nodes ranging from 0.5 to 4.2 cm in greatest dimension. All lymph nodes will be sampled. "E1-E3," representative.

"F, Left pelvic lymph nodes." Received is a 7.2 x 4.1 x 1.8 cm aggregate of yellow-tan, lobulated tissue fragments. On sectioning, there are 7 possible lymph nodes ranging from 0.8 to 2.7 cm. All lymph nodes will be sampled. "F1-F2," representative.

Also received in container labeled " " The container has 2 cassettes, 1 yellow cassette that is labeled " " and 1 green cassette labeled " "

Performing Lab

Testing performed at

[page 3 of 4]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status: Auth (Verified)
Result Title: Surgical Pathology Final Report
Verified By:
Encounter info:

*** Final Report ***

Final Diagnosis (Verified)

Urinary bladder tumor, curettings:

Urothelial carcinoma, high-grade, with invasion of muscularis propria.

Signature Line

Clinical Information (Verified)

Bladder tumor.

Performing Lab (Verified)

Testing performed at

Gross Description (Verified)

"A, Bladder tumor." The specimen consists of a 13 gram aggregate, 4 x 3.8 x 1.2 cm aggregate of soft, friable, red-gray tissue. "A1-A5," fragments, all.

Signature Line

Printed by:

Printed on:

Page 1 of 2
(Continued)

[page 4 of 4]
Surg Path Final Report

* Final Report *

Completed Action List

- * Order by f
- * Order by
- * VERIFY by

Printed by: -
Printed on:

Source: NCI Genomic Data Commons file 0dfa542b-6248-4d5c-b16c-3bf768556c5e (TCGA-GC-A3RC.77A23BED-7B17-4854-A6E3-D6E8ECD460F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).